Somatic mutation profile of tumor specimen C3L-08146-01 (aliquot CPT0511280006) from CPTAC case C3L-08146, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 52.1 years (19,043 days).
Specimen C3L-08146-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 937b50ec-c470-4c80-8340-eada36cec632.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08146-31 (Blood Derived Normal), aliquot CPT0511270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c3446b1-58f5-43cf-ac8d-ca3b603ddc86

The open-access MAF lists 81 somatic variants for this specimen: 50 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 28, Nonsense Mutation 6, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2540T>C p.L847P | Missense Mutation (SNP) | VAF 23/430 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs199474747, CM000793, CM143345, COSV62203716, COSV62227360; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TGFBR2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 36/504 reads (7%) | catalogued as rs863223852, CM063204, COSV55443474; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- ABCC9 | c.2950C>T p.R984C | Missense Mutation (SNP) | VAF 23/391 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs78979794; ClinVar: uncertain significance; called by muse, mutect2
- ACOT1 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 40/724 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs746882222, COSV58574813; called by muse, mutect2
- ACVR2A | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54024943; called by muse, mutect2
- ADGRA2 | c.2947G>A p.G983S | Missense Mutation (SNP) | VAF 32/686 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as rs1228938865; called by muse, mutect2
- AIF1L | c.5C>G p.S2W | Missense Mutation (SNP) | VAF 40/695 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1050280684; called by muse, mutect2
- AMOTL1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 32/712 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1466689580, COSV100133895; called by muse, mutect2
- ANKRD24 | c.1800A>C p.K600N | Missense Mutation (SNP) | VAF 38/636 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.107); catalogued as COSV53671396; called by muse, mutect2
- APLP1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 27/488 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs775672735; called by muse, mutect2
- BAG6 | c.2834G>A p.R945H (on ENST00000676571; = p.R898H on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/611 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs891918045, COSV99057666; called by muse, mutect2
- CELF4 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 38/498 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs367780273; called by muse, mutect2
- CHD3 | c.2467C>T p.R823W | Missense Mutation (SNP) | VAF 34/516 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57880159; called by muse, mutect2
- DMBT1 | c.6412G>A p.G2138R (on ENST00000338354 / NM_001377530.1; = p.G1381R on NM_004406.3) | Missense Mutation (SNP) | VAF 22/381 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs553177521; called by muse, mutect2
- DOCK9 | c.259C>T p.R87* (on ENST00000376460 / NM_001366676.2; = p.R88* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 39/359 reads (11%) | catalogued as rs1330301651; called by muse, mutect2, varscan2
- HHIPL1 | c.1494C>A p.F498L | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs895173398; called by muse, mutect2
- IGF1R | c.3583G>A p.V1195I | Missense Mutation (SNP) | VAF 21/287 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs201014974; called by muse, mutect2
- IGHG3 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 35/734 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.615); catalogued as rs587730662; called by muse, mutect2
- KLRC3 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 20/338 reads (6%) | catalogued as COSV101122924; called by muse, mutect2
- LRRC8B | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 35/464 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as rs750444236; called by muse, mutect2
- NALCN | c.2534G>C p.R845T | Missense Mutation (SNP) | VAF 37/589 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.218); catalogued as COSV51933359; called by muse, mutect2
- OR5V1 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 26/429 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.955); catalogued as COSV65831036; called by muse, mutect2
- POLR3B | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 40/659 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV57276089; called by muse, mutect2
- SBF2 | c.915T>G p.C305W | Missense Mutation (SNP) | VAF 19/373 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56299036; called by muse, mutect2
- SECISBP2L | c.2221C>A p.P741T (on ENST00000559471 / NM_001193489.2; = p.P696T on NM_014701.4) | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55935468; called by muse, mutect2
- TAL1 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 31/565 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1313846024, COSV99595977; called by muse, mutect2
- TRIM58 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 34/508 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63571983; called by muse, mutect2
- TYR | c.236C>A p.S79* | Nonsense Mutation (SNP) | VAF 26/514 reads (5%) | catalogued as CM041463, COSV54472966; called by muse, mutect2
- ZBTB21 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 26/573 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219915702, COSV60404350; called by muse, mutect2
- ZFHX2 | c.6502C>T p.R2168C | Missense Mutation (SNP) | VAF 57/681 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs974247986; called by muse, mutect2
- ZKSCAN8 | c.1613G>T p.R538I | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57636753; called by muse, mutect2
- ADGRE3 | c.1028T>C p.V343A | Missense Mutation (SNP) | VAF 22/379 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- BACH1 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C10orf67 | c.383A>C p.K128T (on ENST00000323327; = p.K129T on NM_153714.3) | Missense Mutation (SNP) | VAF 15/426 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); called by muse, mutect2
- CCDC141 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 24/355 reads (7%) | called by muse, mutect2
- CSMD1 | c.2506C>A p.Q836K (on ENST00000520002; = p.Q835K on NM_033225.6) | Missense Mutation (SNP) | VAF 20/552 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2
- EPN2 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 15/393 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2
- FAT3 | c.6676G>T p.D2226Y | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FREM3 | c.665A>C p.K222T | Missense Mutation (SNP) | VAF 60/792 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2
- GPC4 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 30/372 reads (8%) | called by muse, mutect2
- ITPRID1 | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2
- KCNB2 | c.2479G>A p.V827M | Missense Mutation (SNP) | VAF 23/530 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2
- MGAM2 | c.4094A>C p.K1365T | Missense Mutation (SNP) | VAF 31/436 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- PREX2 | c.2485G>T p.A829S | Missense Mutation (SNP) | VAF 21/495 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPN6 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 20/423 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SRRD | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SSU72P3 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 30/619 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- TENM4 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 43/745 reads (6%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.041); called by muse, mutect2
- TMEM170B | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ZFHX4 | c.2874C>A p.F958L | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ANAPC1 | c.3183G>A p.E1061= | Silent (SNP) | VAF 12/332 reads (4%) | called by muse, mutect2
- ARMH1 | c.1086C>T p.H362= | Silent (SNP) | VAF 28/553 reads (5%) | called by muse, mutect2
- BAHCC1 | c.5151C>T p.S1717= | Silent (SNP) | VAF 32/584 reads (5%) | called by muse, mutect2
- CBLN2 | c.504A>G p.P168= | Silent (SNP) | VAF 29/465 reads (6%) | catalogued as rs755512890; called by muse, mutect2
- CDH9 | c.1209A>G p.G403= | Silent (SNP) | VAF 29/354 reads (8%) | catalogued as COSV50531913; called by muse, mutect2
- CGNL1 | c.2595G>T p.T865= | Silent (SNP) | VAF 19/378 reads (5%) | called by muse, mutect2
- COL15A1 | c.366G>T p.L122= | Silent (SNP) | VAF 36/608 reads (6%) | called by muse, mutect2
- DYRK2 | c.651C>T p.H217= (on ENST00000344096 / NM_006482.3; = p.H144= on NM_003583.4) | Silent (SNP) | VAF 26/507 reads (5%) | catalogued as rs1409963245, COSV59847590; called by muse, mutect2
- FAT3 | c.12639C>T p.R4213= | Silent (SNP) | VAF 40/780 reads (5%) | catalogued as COSV53078901; called by muse, mutect2
- FNDC1 | c.1716C>T p.H572= | Silent (SNP) | VAF 34/685 reads (5%) | catalogued as rs780534302; called by muse, mutect2
- GREB1 | c.4596C>T p.P1532= | Silent (SNP) | VAF 25/412 reads (6%) | catalogued as rs764109148, COSV52187636; called by muse, mutect2
- HPS6 | c.225G>A p.Q75= | Silent (SNP) | VAF 47/800 reads (6%) | called by muse, mutect2
- IRF2BP2 | c.651C>T p.S217= | Silent (SNP) | VAF 47/684 reads (7%) | catalogued as rs772352778; called by muse, mutect2
- KDM3B | c.2397G>A p.L799= | Silent (SNP) | VAF 40/402 reads (10%) | called by muse, mutect2
- KPRP | c.390T>C p.T130= | Silent (SNP) | VAF 21/500 reads (4%) | called by muse, mutect2
- OR5J2 | c.228A>G p.A76= | Silent (SNP) | VAF 32/474 reads (7%) | called by muse, mutect2
- OR8J2 | c.756T>C p.Y252= | Silent (SNP) | VAF 12/370 reads (3%) | catalogued as rs578058714; called by muse, mutect2
- PCDHA11 | c.1440C>T p.D480= | Silent (SNP) | VAF 44/974 reads (5%) | catalogued as rs1554164396, COSV56554757; called by muse, mutect2
- PERM1 | c.1902G>A p.P634= | Silent (SNP) | VAF 36/796 reads (5%) | catalogued as rs575660840, COSV100379093; called by muse, mutect2
- POC1A | c.993C>T p.D331= | Silent (SNP) | VAF 27/382 reads (7%) | catalogued as rs768712874; called by muse, mutect2
- PRPH | c.447C>T p.R149= | Silent (SNP) | VAF 50/861 reads (6%) | catalogued as rs1206874660; called by muse, mutect2
- SHH | c.1227C>T p.G409= | Silent (SNP) | VAF 38/820 reads (5%) | called by muse, mutect2
- SHROOM2 | c.915C>T p.P305= | Silent (SNP) | VAF 43/369 reads (12%) | catalogued as rs372285834, COSV66605358; called by muse, mutect2, varscan2
- SPTBN5 | c.8706C>T p.A2902= | Silent (SNP) | VAF 37/791 reads (5%) | catalogued as rs766773113, COSV58025392, COSV58026940; called by muse, mutect2
- SVIL | c.2643C>T p.T881= (on ENST00000355867 / NM_021738.3; = p.T455= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/433 reads (5%) | catalogued as rs558236640; called by muse, mutect2
- THBS2 | c.1068G>A p.P356= | Silent (SNP) | VAF 26/477 reads (5%) | catalogued as rs1013908512; called by muse, mutect2
- TMEM129 | c.879C>T p.A293= | Silent (SNP) | VAF 40/595 reads (7%) | called by muse, mutect2
- ZNF595 | c.510G>A p.E170= | Silent (SNP) | VAF 20/323 reads (6%) | catalogued as COSV100227520; called by muse, mutect2
- AC109583.1 | c.-542-14228C>T | Intron (SNP) | VAF 40/340 reads (12%) | catalogued as rs758469398; called by muse, mutect2
- CGB7 | c.-2298G>A | 5'UTR (SNP) | VAF 26/660 reads (4%) | called by muse, mutect2
- RPL28 | c.205+149T>G | Intron (SNP) | VAF 31/603 reads (5%) | called by muse, mutect2
